Somatic mutation profile of tumor specimen TCGA-13-1511-01A (aliquot TCGA-13-1511-01A-01W-0545-08) from TCGA case TCGA-13-1511, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 52.7 years (19,258 days).
Specimen TCGA-13-1511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8f60ff4-fe6b-481b-b8b5-8f0c71ba1b5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1511-10A (Blood Derived Normal), aliquot TCGA-13-1511-10A-01W-0546-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02c72f26-3c14-469d-bbca-2671e1e7e391

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 149/166 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGL | c.1864A>G p.M622V | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs145517369, COSV99649401; called by muse, mutect2, varscan2
- ALDH6A1 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 68/174 reads (39%) | catalogued as rs774141754, COSV100620903, COSV63246369; called by muse, mutect2, varscan2
- ENPP2 | c.2399C>T p.P800L (on ENST00000075322 / NM_001040092.3; = p.P852L on NM_006209.5) | Missense Mutation (SNP) | VAF 115/510 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV99308494; called by muse, mutect2, varscan2
- JAKMIP1 | c.1698G>T p.L566F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99289834; called by muse, mutect2, varscan2
- LRP1B | c.10801T>G p.C3601G | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV101257793; called by muse, mutect2, varscan2
- MTMR2 | c.1378T>C p.F460L | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60582862; called by muse, mutect2, varscan2
- TBP | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 68/82 reads (83%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as COSV100027363; called by muse, mutect2, varscan2
- CDK12 | c.174del p.E59Kfs*33 | Frame Shift Del (DEL) | VAF 172/204 reads (84%) | called by mutect2, varscan2
- DNMT3A | c.1542_1554del p.C514* | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- PYGB | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.564); called by muse, mutect2
- HAO2 | c.294G>A p.A98= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs372674483; called by muse, mutect2, varscan2
- MTUS2 | c.2751G>A p.V917= | Silent (SNP) | VAF 21/156 reads (13%) | catalogued as COSV54996343; called by muse, varscan2
- STRAP | c.480T>C p.S160= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV99214819; called by muse, mutect2, varscan2
- NTNG1 | c.1087+10881A>C | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs1393533815, COSV100903500; called by muse, mutect2
- PFKFB3 | c.1515+1855dup | Intron (INS) | VAF 53/141 reads (38%) | called by mutect2, pindel, varscan2
